Somatic mutation profile of tumor specimen C3N-03011-01 (aliquot CPT0226250007) from CPTAC case C3N-03011, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 62.6 years (22,872 days).
Specimen C3N-03011-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ab8f039-9a0e-4802-8bee-225db1805304.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03011-31 (Blood Derived Normal), aliquot CPT0226330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0d32c3d-050c-44d8-923f-57eca19e5b46

The open-access MAF lists 81 somatic variants for this specimen: 60 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, 3'UTR 5, Nonsense Mutation 3, Frame Shift Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGHMBP2 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 150/1648 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754465226, COSV54827359; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 467/645 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C4orf54 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV101552117; called by muse, mutect2, varscan2
- DDB1 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.662); catalogued as rs373150519; called by muse, mutect2, varscan2
- DDR1 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs143357711; called by muse, mutect2, varscan2
- DRD2 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 120/183 reads (66%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs373984882; called by muse, mutect2, varscan2
- GALNT13 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV101222879; called by muse, mutect2, varscan2
- GPR153 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 268/395 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs769601920, COSV64938574; called by muse, mutect2, varscan2
- GTF2I | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs202085514; called by muse, mutect2, varscan2
- ICE1 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs1420999813; called by muse, mutect2, varscan2
- L1CAM | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 70/88 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs782727308; called by muse, mutect2, varscan2
- OR5M3 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs769332657, COSV56566646; called by muse, mutect2, varscan2
- PDXDC1 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV57908201; called by muse, mutect2, varscan2
- PIGQ | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.687); catalogued as rs376046019; called by muse, mutect2
- POR | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782334391; called by muse, mutect2, varscan2
- RIPPLY2 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs1462742124, COSV63763108; called by muse, mutect2
- SLC25A45 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as rs565926011, COSV53683417; called by muse, mutect2, varscan2
- SLC39A11 | c.850G>A p.V284M (on ENST00000542342 / NM_001159770.2; = p.V277M on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs553583617; called by muse, mutect2, varscan2
- TRPC5 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 112/151 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs962685683, COSV53303315; called by muse, mutect2, varscan2
- TUBB4A | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 71/426 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs1196637862, COSV51163156; called by muse, mutect2, varscan2
- ZDHHC17 | c.1054C>G p.H352D | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.147); catalogued as rs759178965; called by muse, mutect2, varscan2
- ZNF831 | c.2054C>T p.S685F | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV64037129; called by muse, mutect2, varscan2
- AHI1 | c.1869A>G p.I623M | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ATG16L2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 141/1001 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- B4GALNT4 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CCNG1 | c.467A>T p.Q156L | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CENPF | c.7921G>A p.G2641R | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CXXC4 | c.278A>T p.N93I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- EMC1 | c.2735A>G p.Y912C | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSCN2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 167/438 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGB1 | c.7273A>G p.I2425V | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GRAMD2A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- HRNR | c.1928C>G p.S643* | Nonsense Mutation (SNP) | VAF 50/1142 reads (4%) | called by muse, mutect2
- IL18 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- IL3RA | c.829A>G p.R277G | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- KHDC4 | c.1196_1208del p.P399Hfs*9 | Frame Shift Del (DEL) | VAF 61/278 reads (22%) | called by mutect2, pindel, varscan2
- KLF16 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.048); called by muse, mutect2
- LEMD3 | c.2492A>G p.E831G | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAGI2 | c.1558G>C p.A520P | Missense Mutation (SNP) | VAF 165/475 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- MB21D2 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MYRF | c.3310C>T p.H1104Y (on ENST00000278836 / NM_001127392.3; = p.H1064Y on NM_013279.4) | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NACA | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 109/348 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- NRCAM | c.733A>C p.N245H (on ENST00000379028 / NM_001371124.1; = p.N239H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2
- NSMAF | c.1738T>C p.F580L | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUF2 | c.159A>C p.L53F | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLXNB2 | c.4837C>T p.R1613W | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBBP5 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 30/329 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- RRN3 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SERINC3 | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SLC35B1 | c.1028-4A>T | Splice Region (SNP) | VAF 37/129 reads (29%) | called by muse, mutect2, varscan2
- SMAP1 | c.156T>G p.I52M | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- SYNE2 | c.9088G>T p.E3030* | Nonsense Mutation (SNP) | VAF 35/61 reads (57%) | called by muse, mutect2, varscan2
- TASP1 | c.566C>A p.T189K | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TDRD6 | c.1733T>A p.V578E | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPC4AP | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ZBTB41 | c.2239C>T p.H747Y | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZFAND3 | c.403C>G p.R135G | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZNF43 | c.1277A>G p.Y426C | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF750 | c.1588C>A p.P530T | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF805 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- AFG3L2 | c.1602G>A p.R534= | Silent (SNP) | VAF 93/276 reads (34%) | called by muse, mutect2, varscan2
- COPB2 | c.2076T>C p.H692= | Silent (SNP) | VAF 120/197 reads (61%) | catalogued as rs768857801; called by muse, mutect2, varscan2
- CORO1A | c.1119C>A p.A373= | Silent (SNP) | VAF 83/369 reads (22%) | called by muse, mutect2, varscan2
- GABBR1 | c.1998C>T p.R666= | Silent (SNP) | VAF 86/202 reads (43%) | called by muse, mutect2, varscan2
- GAK | c.1122C>T p.F374= | Silent (SNP) | VAF 97/165 reads (59%) | called by muse, mutect2, varscan2
- GPR149 | c.1380C>G p.P460= | Silent (SNP) | VAF 66/220 reads (30%) | catalogued as rs974330138; called by muse, mutect2, varscan2
- IL22 | c.102G>A p.A34= | Silent (SNP) | VAF 99/353 reads (28%) | catalogued as COSV100048857; called by muse, mutect2, varscan2
- LSM14A | c.1098T>G p.T366= | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- PNLIP | c.729C>T p.F243= | Silent (SNP) | VAF 52/183 reads (28%) | catalogued as COSV65040228; called by muse, mutect2, varscan2
- RABAC1 | c.201C>T p.L67= | Silent (SNP) | VAF 106/407 reads (26%) | called by muse, mutect2, varscan2
- SLC5A6 | c.1674C>T p.N558= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs762605889; called by muse, mutect2, varscan2
- THEMIS | c.1677A>G p.K559= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs758952233; called by muse, mutect2, varscan2
- UBALD2 | c.228C>T p.P76= | Silent (SNP) | VAF 248/669 reads (37%) | catalogued as rs201590446; called by muse, mutect2, varscan2
- VPS13D | c.12369G>A p.T4123= | Silent (SNP) | VAF 72/120 reads (60%) | catalogued as rs1411757574; called by muse, mutect2, varscan2
- ZNF24 | c.876C>T p.S292= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- BLVRA | c.*51C>T | 3'UTR (SNP) | VAF 19/295 reads (6%) | called by muse, mutect2
- COL15A1 | c.*781A>T | 3'UTR (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- EIF3B | c.*172G>T | 3'UTR (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- FAM214B | c.*592C>T | 3'UTR (SNP) | VAF 7/17 reads (41%) | catalogued as rs1249833637; called by muse, mutect2
- FCRL5 | c.1681+291G>C | Intron (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- PTDSS1 | c.*219C>G | 3'UTR (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
